Somatic mutation profile of tumor specimen TCGA-HZ-8003-01A (aliquot TCGA-HZ-8003-01A-21D-2201-08) from TCGA case TCGA-HZ-8003, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 65.3 years (23,868 days).
Specimen TCGA-HZ-8003-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a27e346a-62c6-4af9-a0f5-f90c82949431.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HZ-8003-10A (Blood Derived Normal), aliquot TCGA-HZ-8003-10A-01D-2201-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/42148045-2046-4408-8b95-32d1fe28a0a6

The open-access MAF lists 13 somatic variants for this specimen: 7 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 7, Silent 6.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP3D1 | c.2914C>T p.L972F | Missense Mutation (SNP) | VAF 14/307 reads (5%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.924); catalogued as COSV100642392; called by muse, mutect2
- MAP7D3 | c.1405G>A p.A469T | Missense Mutation (SNP) | VAF 36/1396 reads (3%) | SIFT tolerated (0.56); PolyPhen benign (0.011); catalogued as rs1343226323, COSV60170053; called by muse, mutect2
- RPH3A | c.290G>A p.R97H (on ENST00000389385 / NM_001143854.2; = p.R93H on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/752 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.541); catalogued as rs199724124, COSV66992806; called by muse, mutect2
- SLC45A2 | c.1235C>T p.T412M | Missense Mutation (SNP) | VAF 44/1098 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); catalogued as rs149980670; ClinVar: uncertain significance; called by muse, mutect2
- SPTA1 | c.2548C>G p.Q850E | Missense Mutation (SNP) | VAF 24/976 reads (2%) | SIFT tolerated (0.43); PolyPhen benign (0.012); catalogued as COSV100934291, COSV63748902; called by muse, mutect2
- TUBGCP6 | c.1781A>G p.D594G | Missense Mutation (SNP) | VAF 40/1485 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99954850; called by muse, mutect2
- TULP4 | c.4005G>C p.K1335N | Missense Mutation (SNP) | VAF 14/442 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100893140; called by muse, mutect2
- DHX58 | c.384C>T p.I128= | Silent (SNP) | VAF 33/986 reads (3%) | catalogued as rs782619499, COSV52426337, COSV52427881; called by muse, mutect2
- EZR | c.753T>C p.N251= | Silent (SNP) | VAF 26/760 reads (3%) | catalogued as COSV100454753; called by muse, mutect2
- IFT122 | c.2187C>T p.L729= (on ENST00000348417 / NM_052989.3; = p.L670= on NM_018262.4) | Silent (SNP) | VAF 19/587 reads (3%) | catalogued as COSV56203951, COSV99958745; called by muse, mutect2
- SLC4A5 | c.2019C>T p.F673= | Silent (SNP) | VAF 68/1846 reads (4%) | catalogued as COSV100697408; called by muse, mutect2
- TRPS1 | c.2682T>A p.V894= (on ENST00000220888 / NM_001330599.2; = p.V907= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 37/1020 reads (4%) | catalogued as COSV99628522; called by muse, mutect2
- TXNIP | c.552T>A p.I184= | Silent (SNP) | VAF 51/1343 reads (4%) | catalogued as COSV100997256; called by muse, mutect2
